Gene-level copy-number profile of tumor specimen HCM-CSHL-0244-C20-01B from HCMI case HCM-CSHL-0244-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 61.0 years (22,290 days).
Specimen HCM-CSHL-0244-C20-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a85bbe63-3453-42a7-a11f-03c27ff1d592.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0244-C20-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/8be1564c-d7fd-401a-9706-697f1d454e6b

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 514; copy number 1: 32,500; copy number 2: 25,808; copy number 3: 69; copy number 4: 16; copy number 9: 2; copy number 14: 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:43,211,791–43,269,530, 2 genes: CEACAMP10, PSG9.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 88 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:187,003,220–187,556,288, 1 gene, copy number 3 (within-gene range 2–3): AC007319.1.
- chr2:187,270,698–187,448,460, 3 genes, copy number 3: RNU6-989P, CALCRL, GAPDHP59.
- chr2:190,908,460–191,174,835, 9 genes, copy number 3 (within-gene range 2–3): STAT1, RAB1AP1, AC067945.1, AC067945.2, STAT4, AC067945.3, RNU6-959P, AC079777.1, HMGB1P27.
- chr2:231,961,245–232,344,350, 3 genes, copy number 3 (within-gene range 2–3): DIS3L2, AC019130.1, MIR562.
- chr6:170,639,606–170,737,777, 3 genes, copy number 4: OR4F7P, WBP1LP8, AL731684.1.
- chr7:62,275,361–62,275,678, 1 gene, copy number 3: AC128676.1.
- chr10:3,232,264–5,304,865, 37 genes, copy number 3: LINC02668, AL139280.1, LINC02669, AL357833.1, AL450322.2, AL450322.1, KLF6, LINC02639, LINC02660, MIR6078, AC025822.1, AC025822.2, LINC00702, LINC00703, AC022535.1, AC022535.2, RNU6-163P, MANCR, LINC00705, AKR1E2, AKR1C6P, U8, AKR1C1, AKR1C2, AL391427.1, U8, AKR1C3, U8, AKR1C5P, AKR1C8P, AKR1C4, ARL4AP3, AL355303.2, AL355303.1, LINC02561, AKR1C7P, RPL26P28.
- chr10:42,149,310–42,281,819, 5 genes, copy number 3: KSR1P1, IGKV1OR10-1, AL031601.1, AL031601.2, PABPC1P8.
- chr13:26,905,362–27,182,998, 8 genes, copy number 4 (within-gene range 2–4): FGFR1OP2P1, AL160035.1, RPS21P8, RPS20P32, USP12, AL158062.1, USP12-AS1, USP12-AS2.
- chr16:33,802,764–33,810,767, 2 genes, copy number 9: IGHV3OR16-12, AC136428.3.
- chr17:21,592,794–21,594,180, 1 gene, copy number 3: AC233702.2.
- chr17:48,133,442–48,430,275, 1 gene, copy number 4 (within-gene range 2–4): SKAP1.
- chr17:48,185,938–48,382,586, 5 genes, copy number 3–4: SKAP1-AS1, RNU6-1152P, THRA1/BTR, AC036222.2, U3.
- chr19:1,039,997–1,086,628, 2 genes, copy number 3 (within-gene range 2–3): ABCA7, ARHGAP45.
- chr19:1,397,026–1,435,687, 2 genes, copy number 3: GAMT, DAZAP1.
- chr19:1,505,022–1,536,046, 3 genes, copy number 3: ADAMTSL5, PLK5, AC027307.1.
- chr22:18,873,543–18,894,407, 1 gene, copy number 4 (within-gene range 1–4): FAM230F.
- chr22:18,906,028–18,914,238, 1 gene, copy number 14 (within-gene range 1–14): DGCR6.

Autosomal genes at a single copy (total copy number 1): 30,265. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
